Somatic mutation profile of tumor specimen 0DUIXS from CCDI case PBCLLD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,025 days).
Specimen 0DUIXS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53a5f94f-5077-4476-abe3-9b59902480a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07a41f6e-7520-49c0-9e5b-85f03071dc8d

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, 3'UTR 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 170/472 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 492/495 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACSL1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 210/213 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs755845769, COSV99860839; called by muse, varscan2
- ADH1A | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 162/176 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99266024; called by muse, varscan2
- ANO10 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769678648, COSV52730019; called by muse, varscan2
- CYP46A1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs775557276, COSV99952866; called by muse, varscan2
- DDX49 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 180/356 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs373378963; called by muse, varscan2
- DEFB113 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 104/106 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV67143245, COSV67143452; called by muse, varscan2
- EYS | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 180/299 reads (60%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.023); catalogued as COSV100676375; called by muse, varscan2
- ITGB6 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs760097625; called by muse, varscan2
- KLRF1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1432582574; called by muse, varscan2
- NCKAP5 | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100491360; called by muse, varscan2
- NLRX1 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs766310885, COSV52706175; called by muse, varscan2
- RADIL | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs369056417; called by muse, varscan2
- TRIM38 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 124/172 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62642896; called by muse, varscan2
- ZDHHC9 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 95/100 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1257860957, COSV104420776; called by muse, varscan2
- ZNF878 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 182/422 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs373583823; called by muse, varscan2
- KANSL3 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 126/226 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, varscan2
- PHOX2A | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0.04); called by muse, varscan2
- CACNG8 | c.1038C>A p.G346= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- CCDC3 | c.310C>T p.L104= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as rs1373411248; called by muse, varscan2
- CNKSR1 | c.1251C>A p.G417= (on ENST00000374253 / NM_001297647.2; = p.G410= on NM_006314.3) | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, varscan2
- NFATC2 | c.396C>T p.D132= | Silent (SNP) | VAF 79/161 reads (49%) | catalogued as rs1475257769, COSV65357639; called by muse, varscan2
- PNPLA1 | c.276G>A p.P92= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as rs749816424; called by muse, varscan2
- TRIM72 | c.1311G>A p.P437= | Silent (SNP) | VAF 66/90 reads (73%) | catalogued as rs1224431203; called by muse, varscan2
- GRWD1 | c.*100C>T | 3'UTR (SNP) | VAF 10/16 reads (63%) | catalogued as rs1043520859; called by muse, varscan2
- PNKD | c.*46C>T | 3'UTR (SNP) | VAF 30/46 reads (65%) | catalogued as rs562448833; called by muse, varscan2
- PPHLN1 | c.1126-179G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 33/180 reads (18%) | called by muse, varscan2
- ZNF598 | c.335+53C>T | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1441629369; called by muse, varscan2
